Somatic mutation profile of tumor specimen ALCH-B0BU-TTP1-A (aliquot ALCH-B0BU-TTP1-A-1-0-D-A694-36) from ALCHEMIST case ALCH-B0BU, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.7 years (22,159 days).
Specimen ALCH-B0BU-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04956773-629e-4f8a-9d22-181d86971258.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0BU-NB1-A (Blood Derived Normal), aliquot ALCH-B0BU-NB1-A-1-0-D-A695-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0eccbddc-9ba4-4ba0-95c6-e23f6b643b94

The open-access MAF lists 65 somatic variants for this specimen: 51 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 11, Nonsense Mutation 3, 3'UTR 2, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CELSR2 | c.1118G>A p.G373D | Missense Mutation (SNP) | VAF 34/488 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1376040101; called by muse, mutect2
- COL2A1 | c.2869G>T p.G957* | Nonsense Mutation (SNP) | VAF 18/436 reads (4%) | catalogued as CM103266; called by muse, mutect2
- DGCR2 | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 88/1308 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs1402145000; called by muse, mutect2
- ERICH3 | c.1169G>T p.R390I | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs1238064275; called by muse, mutect2
- ESS2 | c.62G>A p.R21K | Missense Mutation (SNP) | VAF 124/226 reads (55%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs1288488136; called by muse, mutect2, varscan2
- GNAS | c.1640G>A p.R547H | Missense Mutation (SNP) | VAF 28/734 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as rs1388507499, COSV100005176; called by muse, mutect2
- GSC2 | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 187/351 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs782051073; called by muse, varscan2
- HECTD4 | c.8878A>G p.I2960V | Missense Mutation (SNP) | VAF 39/865 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs1249584368; called by muse, mutect2
- NOG | c.413G>A p.S138N | Missense Mutation (SNP) | VAF 20/360 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.854); catalogued as rs1003152912; called by muse, mutect2
- NR5A1 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 24/684 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs1185991537, COSV65295550; called by muse, mutect2
- PCDHB4 | c.2384G>T p.S795I | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); catalogued as rs546746966; called by muse, mutect2
- PIK3CG | c.2807G>T p.C936F | Missense Mutation (SNP) | VAF 16/378 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV63250026; called by muse, mutect2
- RHO | c.578C>A p.T193K | Missense Mutation (SNP) | VAF 25/454 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373974298, CM984236; called by muse, mutect2
- UNC80 | c.907A>G p.T303A | Missense Mutation (SNP) | VAF 22/300 reads (7%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV55890234, COSV55895785; called by muse, mutect2
- XIRP2 | c.6503G>T p.G2168V (on ENST00000628543; = p.G2343V on NM_152381.6) | Missense Mutation (SNP) | VAF 34/531 reads (6%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.058); catalogued as rs183141849; called by muse, mutect2
- ZNF526 | c.729A>T p.E243D | Missense Mutation (SNP) | VAF 62/1152 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs566910586; called by muse, mutect2
- ADAM22 | c.2336G>T p.G779V | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.826); called by muse, mutect2
- ATP11C | c.2122A>G p.I708V | Missense Mutation (SNP) | VAF 40/536 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.02); called by muse, mutect2
- ATP2B4 | c.1304A>G p.Y435C | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CNN1 | c.236C>A p.T79N | Missense Mutation (SNP) | VAF 25/368 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.029); called by muse, mutect2
- COL11A1 | c.11G>T p.W4L | Missense Mutation (SNP) | VAF 28/830 reads (3%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.018); called by muse, mutect2
- CTSK | c.706A>T p.K236* | Nonsense Mutation (SNP) | VAF 18/477 reads (4%) | called by muse, mutect2
- DNMT1 | c.3486C>G p.D1162E | Missense Mutation (SNP) | VAF 40/717 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- DRICH1 | c.277-2A>T p.X93_splice | Splice Site (SNP) | VAF 40/578 reads (7%) | called by muse, mutect2
- FLT3 | c.2927G>T p.S976I | Missense Mutation (SNP) | VAF 18/560 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.085); called by muse, mutect2
- GRK6 | c.70A>C p.K24Q | Missense Mutation (SNP) | VAF 14/422 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- HERC2 | c.9778G>T p.V3260L | Missense Mutation (SNP) | VAF 22/415 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2
- HPN | c.986G>A p.G329E | Missense Mutation (SNP) | VAF 601/1220 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.114); called by muse, varscan2
- KCNK1 | c.211T>C p.S71P | Missense Mutation (SNP) | VAF 23/503 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.606); called by muse, mutect2
- MCC | c.2263C>T p.H755Y | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2
- MYRFL | c.2560G>C p.E854Q | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.791); called by muse, mutect2
- NPAP1 | c.981A>T p.K327N | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2
- OR13C4 | c.347G>T p.G116V | Missense Mutation (SNP) | VAF 14/352 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.234); called by muse, mutect2
- PIEZO2 | c.2416C>A p.H806N | Missense Mutation (SNP) | VAF 16/275 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2
- PLXDC1 | c.1192A>G p.T398A | Missense Mutation (SNP) | VAF 34/491 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.192); called by muse, mutect2
- PRAMEF2 | c.1224C>A p.S408R | Missense Mutation (SNP) | VAF 22/620 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.009); called by muse, mutect2
- PRKDC | c.6275A>T p.E2092V | Missense Mutation (SNP) | VAF 24/354 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.376); called by muse, mutect2
- RNF44 | c.964A>T p.T322S | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.009); called by muse, mutect2
- RPGR | c.3031G>C p.E1011Q (on ENST00000339363 / NM_001367249.1; = p.E806Q on NM_000328.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/301 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.446); called by muse, mutect2
- RTP3 | c.144G>A p.W48* | Nonsense Mutation (SNP) | VAF 19/317 reads (6%) | called by muse, mutect2
- SEC14L4 | c.1102A>T p.T368S | Missense Mutation (SNP) | VAF 16/369 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.017); called by muse, mutect2
- SHC3 | c.526A>G p.T176A | Missense Mutation (SNP) | VAF 34/258 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- SLC5A8 | c.128A>G p.K43R | Missense Mutation (SNP) | VAF 13/199 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.006); called by muse, mutect2
- SPPL2B | c.529A>G p.I177V | Missense Mutation (SNP) | VAF 11/254 reads (4%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.472); called by muse, mutect2
- TRMT12 | c.130G>C p.D44H | Missense Mutation (SNP) | VAF 47/609 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.425); called by muse, mutect2
- TRMT12 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 44/419 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.345); called by muse, varscan2
- TRMT12 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 62/534 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.329); called by muse, mutect2
- TRMT12 | c.546T>G p.D182E | Missense Mutation (SNP) | VAF 64/548 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2
- TSPAN17 | c.25C>A p.Q9K | Missense Mutation (SNP) | VAF 54/396 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- UNC80 | c.1906G>C p.E636Q | Missense Mutation (SNP) | VAF 19/423 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.192); called by muse, mutect2
- ZNF239 | c.754A>G p.I252V | Missense Mutation (SNP) | VAF 36/627 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- ADAMTS12 | c.405T>A p.S135= | Silent (SNP) | VAF 15/336 reads (4%) | catalogued as rs17854968; called by muse, mutect2
- BCL9 | c.1506C>G p.V502= | Silent (SNP) | VAF 20/512 reads (4%) | called by muse, mutect2
- CNN1 | c.237C>A p.T79= | Silent (SNP) | VAF 24/364 reads (7%) | called by muse, mutect2
- CYP2A6 | c.276G>A p.V92= | Silent (SNP) | VAF 79/543 reads (15%) | catalogued as rs764214264; called by muse, mutect2, varscan2
- CYP51A1 | c.1176T>C p.T392= | Silent (SNP) | VAF 25/254 reads (10%) | catalogued as rs751231020; called by muse, mutect2, varscan2
- HPN | c.1248G>A p.Q416= | Silent (SNP) | VAF 296/626 reads (47%) | called by muse, mutect2, varscan2
- KIR2DL4 | c.1236A>G p.P412= (on ENST00000396284; = p.P338= on NM_001080770.2) | Silent (SNP) | VAF 14/280 reads (5%) | catalogued as rs1269953283; called by muse, mutect2
- NEK5 | c.2100G>A p.P700= | Silent (SNP) | VAF 28/415 reads (7%) | catalogued as rs768804337; called by muse, mutect2
- P3H2 | c.691A>C p.R231= | Silent (SNP) | VAF 22/314 reads (7%) | called by muse, mutect2
- TRAF3 | c.1090C>T p.L364= | Silent (SNP) | VAF 17/262 reads (6%) | called by muse, mutect2
- TROAP | c.1233A>G p.P411= | Silent (SNP) | VAF 25/405 reads (6%) | called by muse, mutect2
- ARFGEF1 | c.*14T>G | 3'UTR (SNP) | VAF 11/156 reads (7%) | called by muse, mutect2
- ERBB4 | c.-41G>C | 5'UTR (SNP) | VAF 32/634 reads (5%) | called by muse, mutect2
- GSC2 | c.*23G>A | 3'UTR (SNP) | VAF 148/269 reads (55%) | called by muse, varscan2
